Somatic mutation profile of tumor specimen 0DFJMY from CCDI case PBBRNV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Aggressive fibromatosis; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 16.2 years (5,908 days).
Specimen 0DFJMY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db8901d3-e90b-431a-bfc4-67ddffd425e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFJJ0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bf72a4f-a1de-4fcc-bed2-4eb6aa4a4e3b

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 2, Silent 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 150/374 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, varscan2
- PIAS1 | c.1528A>G p.S510G | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs755539001; called by muse, mutect2
- SIGLEC9 | c.680C>T p.T227I | Missense Mutation (SNP) | VAF 19/365 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV51586163; called by muse, mutect2
- CENPC | c.710G>A p.R237K | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- LAGE3 | c.379C>A p.L127I | Missense Mutation (SNP) | VAF 30/666 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- MPL | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.152); called by muse, mutect2
- PIK3C2A | c.768A>G p.L256= | Silent (SNP) | VAF 22/358 reads (6%) | called by muse, mutect2
- CYB5D1 | chr17:7866543 G>C | 3'Flank (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- OTOGL | c.6735+14T>A | Intron (SNP) | VAF 18/214 reads (8%) | called by muse, mutect2
- PRKACA | c.47-451T>G | Intron (SNP) | VAF 10/285 reads (4%) | called by muse, mutect2
